Somatic mutation profile of tumor specimen TCGA-EE-A2A0-06A (aliquot TCGA-EE-A2A0-06A-11D-A196-08) from TCGA case TCGA-EE-A2A0, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 80.5 years (29,399 days).
Specimen TCGA-EE-A2A0-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6a0f5a0-96b0-42c2-b8a5-0ba0f8fdf1cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2A0-10A (Blood Derived Normal), aliquot TCGA-EE-A2A0-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4b9bcc6-6b4d-4cc0-8ee1-91b76dbcc874

The open-access MAF lists 453 somatic variants for this specimen: 332 protein-altering or splice-affecting, 110 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 307, Silent 110, Nonsense Mutation 19, Intron 5, Splice Site 4, RNA 3, 3'UTR 2, Splice Region 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1910T>A p.L637Q (on ENST00000288602 / NM_001374244.1; = p.L597Q on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs121913366, COSV56072463, COSV56121113, COSV56136756; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.3937G>A p.V1313M | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs369047089; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB1 | c.3554C>T p.A1185V | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV55950055; called by muse, mutect2, varscan2
- ABCC12 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV60913487, COSV60918548; called by muse, mutect2
- ABCG8 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs776775584, COSV55391415; called by muse, mutect2, varscan2
- ABL2 | c.1123G>A p.E375K (on ENST00000502732 / NM_007314.4; = p.E360K on NM_005158.5) | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as COSV61013390; called by muse, mutect2, varscan2
- ACAN | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.974); catalogued as rs1024890615; called by muse, mutect2, varscan2
- ACSBG1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV51905437; called by muse, mutect2, varscan2
- ACSL5 | c.1046C>T p.P349L (on ENST00000354273; = p.P405L on NM_016234.3) | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV61130352; called by muse, mutect2, varscan2
- ADAM29 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.971); catalogued as COSV63663158; called by muse, mutect2, varscan2
- ADCY8 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53905683; called by muse, mutect2, varscan2
- ADCY8 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201905912, COSV53898118; called by muse, mutect2, varscan2
- ADGRF2 | c.722C>T p.A241V (on ENST00000296862 / NM_001368115.2; = p.A173V on NM_153839.7) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.539); catalogued as COSV57288019; called by muse, mutect2, varscan2
- ADGRL4 | c.1636G>A p.G546R | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66061303; called by muse, varscan2
- ADGRL4 | c.1580G>A p.G527E | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.977); catalogued as COSV66060148, COSV66061309; called by muse, varscan2
- ADH1A | c.958C>T p.L320F | Missense Mutation (SNP) | VAF 50/228 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52924845; called by muse, mutect2, varscan2
- AL162417.1 | c.287C>T p.T96I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV64404396; called by muse, mutect2, varscan2
- AL441992.2 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as COSV56913445; called by muse, mutect2, varscan2
- ALOXE3 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1046226453, COSV59075411; called by muse, mutect2, varscan2
- AMHR2 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 11/103 reads (11%) | catalogued as COSV57685630; called by muse, mutect2, varscan2
- AMPD1 | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1270841231, COSV62415933; called by muse, mutect2, varscan2
- ANK3 | c.10141G>A p.E3381K | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.056); catalogued as COSV55048770; called by muse, mutect2, varscan2
- ANK3 | c.8314G>A p.D2772N | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); catalogued as rs374606176; called by muse, mutect2, varscan2
- ANK3 | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV55055672; called by muse, mutect2, varscan2
- ANKRD13C | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as COSV52031544; called by muse, mutect2, varscan2
- ANKRD30A | c.604A>C p.N202H (on ENST00000611781; = p.N146H on NM_052997.2) | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV64609229; called by muse, mutect2, varscan2
- ASZ1 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV52912623; called by muse, mutect2, varscan2
- ATP10B | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs3749670, COSV58778595; called by muse, mutect2, varscan2
- BAG2 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.216); catalogued as COSV58097812; called by muse, mutect2, varscan2
- BCS1L | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV55307060; called by muse, mutect2, varscan2
- BIRC6 | c.1162A>G p.I388V | Missense Mutation (SNP) | VAF 43/273 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.982); catalogued as COSV70198580; called by muse, mutect2, varscan2
- BMI1 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.709); catalogued as COSV64958987; called by muse, mutect2, varscan2
- BMS1 | c.2815C>T p.R939* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as COSV65733748; called by muse, mutect2, varscan2
- BRAF | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56100061; called by muse, mutect2, varscan2
- BRINP3 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs367902400, COSV66524676; called by muse, mutect2, varscan2
- BRWD1 | c.3643G>C p.V1215L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as COSV60895121; called by muse, mutect2, varscan2
- C2orf49 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.214); catalogued as rs781144157, COSV51527675, COSV51528303; called by mutect2, varscan2
- C9 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.018); catalogued as COSV54674509; called by muse, mutect2, varscan2
- CADPS | c.1925G>A p.G642E | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs529123568, COSV51877512; called by muse, varscan2
- CAPSL | c.316-2A>T p.X106_splice | Splice Site (SNP) | VAF 22/56 reads (39%) | catalogued as COSV68437971; called by muse, mutect2, varscan2
- CATSPERB | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56423395; called by muse, mutect2, varscan2
- CCDC150 | c.3258T>A p.N1086K | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV55873911; called by muse, mutect2, varscan2
- CCDC181 | c.11A>G p.N4S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.225); catalogued as rs759270486, COSV63156288; called by muse, mutect2, varscan2
- CCDC80 | c.2548G>A p.V850M | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52816463; called by muse, mutect2, varscan2
- CCSER1 | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.209); catalogued as rs184476624; called by muse, mutect2
- CD163L1 | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58014686; called by muse, mutect2, varscan2
- CD86 | c.617C>T p.S206L (on ENST00000330540 / NM_175862.5; = p.S200L on NM_006889.4) | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as rs1357097617, COSV52605963; called by muse, mutect2, varscan2
- CD86 | c.744G>A p.W248* (on ENST00000330540 / NM_175862.5; = p.W242* on NM_006889.4) | Nonsense Mutation (SNP) | VAF 12/84 reads (14%) | catalogued as COSV52605989; called by muse, mutect2, varscan2
- CDH17 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs773823130, COSV50327897; called by muse, mutect2, varscan2
- CDH4 | c.1375-1G>A p.X459_splice | Splice Site (SNP) | VAF 9/68 reads (13%) | catalogued as COSV64652410; called by muse, mutect2, varscan2
- CFAP65 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55390099, COSV55390175; called by muse, mutect2, varscan2
- CLVS2 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.79); catalogued as COSV51561523, COSV51566135; called by mutect2, varscan2
- CNBD2 | c.1694A>G p.K565R (on ENST00000373973 / NM_001365709.1; = p.K561R on NM_080834.4) | Missense Mutation (SNP) | VAF 42/291 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1265331694, COSV62586877; called by muse, mutect2, varscan2
- CNTN4 | c.2042G>A p.G681E | Missense Mutation (SNP) | VAF 47/260 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61871961; called by muse, mutect2, varscan2
- CNTN5 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs752165707, COSV54306589; called by mutect2, varscan2
- COL11A1 | c.1811G>A p.G604E | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62181767; called by muse, mutect2, varscan2
- COL12A1 | c.6409G>T p.D2137Y | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59394844; called by muse, mutect2, varscan2
- COL21A1 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55160911; called by muse, mutect2, varscan2
- COL4A5 | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60360642; called by muse, mutect2, varscan2
- COL6A6 | c.2474A>G p.Y825C | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1560007747, COSV62023772; called by muse, mutect2, varscan2
- CPA2 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV55979431, COSV99743725; called by muse, mutect2, varscan2
- CSF2 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); catalogued as COSV51522395; called by muse, mutect2, varscan2
- DBX2 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 20/98 reads (20%) | catalogued as COSV60337400; called by muse, mutect2, varscan2
- DCC | c.2368T>C p.S790P | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59099577; called by muse, mutect2, varscan2
- DDX43 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV64836828; called by muse, mutect2
- DEUP1 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs757502099, COSV53211877; called by muse, mutect2, varscan2
- DIDO1 | c.5308A>G p.N1770D | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as COSV56620831; called by muse, mutect2, varscan2
- DLG1 | c.1493G>A p.G498E | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58381630; called by muse, mutect2, varscan2
- DNAH7 | c.5472G>A p.M1824I | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV56762376; called by muse, mutect2
- DNAH7 | c.3206C>T p.P1069L | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100418379, COSV56762383; called by muse, mutect2, varscan2
- DNMT1 | c.1592T>G p.I531S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as CM152803; called by muse, mutect2, varscan2
- DSCAM | c.3631C>T p.P1211S | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV68019961, COSV68028054, COSV68035453; called by muse, mutect2, varscan2
- DSCAM | c.2068C>T p.P690S | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68021908; called by muse, mutect2, varscan2
- DSG4 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1042293964, COSV57391132; called by muse, mutect2, varscan2
- DYNC2H1 | c.2626C>T p.L876F | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV62092928; called by muse, mutect2
- EFCAB11 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs757985158, COSV50860774; called by muse, mutect2, varscan2
- ELAPOR2 | c.2305G>A p.G769S (on ENST00000450689 / NM_001142749.3; = p.G602S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.873); catalogued as COSV51886303; called by muse, mutect2, varscan2
- EPG5 | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1392476434, COSV56348869; called by muse, mutect2, varscan2
- ERBB4 | c.1367G>A p.G456E | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53527255; called by muse, mutect2, varscan2
- ERC2 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as COSV55604414, COSV55665358; called by muse, mutect2, varscan2
- EXOC1 | c.2309C>T p.S770F | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as COSV62120094; called by muse, mutect2, varscan2
- EZH2 | c.425A>T p.D142V | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV57451836; called by muse, mutect2, varscan2
- FANCM | c.3577C>T p.Q1193* | Nonsense Mutation (SNP) | VAF 9/66 reads (14%) | catalogued as COSV57500421; called by muse, mutect2, varscan2
- FAT4 | c.13467T>A p.H4489Q | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.976); catalogued as COSV58682216; called by muse, varscan2
- FAT4 | c.13507C>T p.P4503S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as COSV58682232; called by muse, varscan2
- FBLN1 | c.2065C>T p.R689* | Nonsense Mutation (SNP) | VAF 38/249 reads (15%) | catalogued as rs775373211, COSV59937540; called by muse, mutect2, varscan2
- FCRL6 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.373); catalogued as COSV58940791; called by muse, mutect2, varscan2
- FLG | c.7558G>A p.D2520N | Missense Mutation (SNP) | VAF 51/320 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs866141505, COSV64236630; called by muse, mutect2, varscan2
- FLG | c.2968G>A p.E990K | Missense Mutation (SNP) | VAF 45/296 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as rs764938074, COSV64241010; called by muse, mutect2, varscan2
- FMN2 | c.5099G>A p.G1700E | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.043); catalogued as COSV60420981; called by muse, mutect2, varscan2
- FREM2 | c.6904G>A p.D2302N | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as rs1366892360, COSV54836112; called by muse, varscan2
- FRG2B | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs1296002932, COSV71042662; called by mutect2, varscan2
- FRMPD2 | c.2546C>T p.S849F | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59717546; called by muse, mutect2, varscan2
- FSIP2 | c.19082G>A p.R6361K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.99); PolyPhen probably damaging (0.954); catalogued as COSV58079790; called by muse, mutect2, varscan2
- GABRB1 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.112); catalogued as COSV54979411, COSV54995219; called by muse, mutect2, varscan2
- GALNT14 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61108112; called by muse, mutect2, varscan2
- GALNT3 | c.1429A>C p.K477Q | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV67061691; called by muse, mutect2, varscan2
- GALNT8 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as rs777239325, COSV52895415, COSV99363168; called by mutect2, varscan2
- GAS2L2 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782266231; called by muse, mutect2, varscan2
- GBP6 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 42/236 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as COSV100969748, COSV65011361; called by muse, mutect2, varscan2
- GLO1 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.527); catalogued as COSV64905137; called by muse, mutect2, varscan2
- GNL2 | c.1762A>G p.N588D | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV56169748; called by muse, mutect2, varscan2
- GP6 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0.01); catalogued as COSV59977232; called by muse, varscan2
- GPR141 | c.897G>A p.W299* | Nonsense Mutation (SNP) | VAF 8/83 reads (10%) | catalogued as COSV57731758; called by muse, mutect2, varscan2
- GPRIN3 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as COSV60884748; called by muse, mutect2, varscan2
- GRID2 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs267600300, COSV56188248; called by muse, varscan2
- GRIK1 | c.2303C>T p.T768I | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58716752; called by muse, mutect2, varscan2
- GRM6 | c.2357G>A p.G786D | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51440131; called by muse, mutect2, varscan2
- GTF3C4 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.292); catalogued as COSV64645281; called by muse, mutect2, varscan2
- GUCY1B1 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV52375276, COSV52375656; called by muse, mutect2, varscan2
- HCN3 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.166); catalogued as COSV64233867; called by muse, mutect2, varscan2
- HECTD2 | c.166A>G p.I56V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV53220629; called by muse, mutect2, varscan2
- HHIP | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs369873424; called by mutect2, varscan2
- HIPK3 | c.659A>G p.N220S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as rs760884860, COSV57562274; called by mutect2, varscan2
- HPS3 | c.2635T>C p.F879L | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV56054046; called by muse, mutect2
- HSD11B1 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.156); catalogued as COSV54826726; called by muse, mutect2, varscan2
- HSPA4L | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV56545163; called by muse, mutect2
- HTR1E | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59507859, COSV59508028; called by muse, mutect2, varscan2
- IFNA17 | c.446G>A p.R149K | Missense Mutation (SNP) | VAF 57/224 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.643); catalogued as rs1554639730, COSV69738142; called by muse, mutect2, varscan2
- IFNA8 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as COSV66504559; called by muse, mutect2, varscan2
- IFNB1 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs181238596, COSV66525312; called by muse, mutect2, varscan2
- IGHV5-51 | c.155G>A p.W52* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as rs1555541360; called by muse, mutect2, varscan2
- IGKV1-5 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as rs532276861; called by muse, mutect2, varscan2
- IL1RL2 | c.257A>C p.E86A | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV51814854; called by muse, mutect2, varscan2
- INTS6L | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 47/252 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV66084156, COSV66084330; called by muse, mutect2, varscan2
- ITGA4 | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs939753024, COSV51999758; called by muse, mutect2, varscan2
- ITGB4 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as rs374855840; called by muse, mutect2, varscan2
- JPT2 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50188748; called by muse, mutect2, varscan2
- KALRN | c.6803C>T p.S2268F (on ENST00000360013 / NM_001024660.4; = p.S571F on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV52255183; called by muse, mutect2, varscan2
- KCNB2 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs756118503, COSV73049946; called by muse, mutect2, varscan2
- KCNIP3 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54668062; called by muse, mutect2
- KCNJ9 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV63631692; called by mutect2, varscan2
- KCTD8 | c.1333C>T p.Q445* | Nonsense Mutation (SNP) | VAF 19/150 reads (13%) | catalogued as COSV63588502, COSV63594237; called by muse, mutect2, varscan2
- KIR3DL2 | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 51/310 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99552082, COSV99552152; called by muse, mutect2, varscan2
- KNDC1 | c.4258C>T p.R1420* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as rs762192073, COSV58835848; called by muse, mutect2, varscan2
- KRT222 | c.485A>T p.K162M | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV67497872, COSV67498194; called by muse, mutect2, varscan2
- LILRB2 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.113); catalogued as COSV58744902; called by muse, varscan2
- LMBR1 | c.1342C>T p.R448* | Nonsense Mutation (SNP) | VAF 46/129 reads (36%) | catalogued as rs1004969335, COSV62219901; called by muse, mutect2, varscan2
- LMTK3 | c.2821G>A p.E941K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs751209205, COSV54311780; called by muse, mutect2, varscan2
- LOXL4 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as rs750766938, COSV53256431; called by muse, mutect2, varscan2
- LRRC49 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs377618599; called by muse, mutect2, varscan2
- LRRC4C | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53418262; called by muse, mutect2, varscan2
- LRRC7 | c.1915C>T p.P639S (on ENST00000651989 / NM_001370785.2; = p.P606S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV50448510; called by muse, mutect2, varscan2
- LYPLA1 | c.412G>A p.G138S | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57604881; called by muse, mutect2, varscan2
- MAGEC1 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV53570262; called by muse, mutect2, varscan2
- MAML1 | c.2875C>T p.Q959* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as COSV52984872; called by muse, mutect2, varscan2
- MAP2K4 | c.436C>T p.L146F | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62257029; called by muse, mutect2, varscan2
- MCCC1 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV55608408; called by muse, mutect2, varscan2
- MDFI | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV57821963; called by muse, mutect2, varscan2
- ME1 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV63838998; called by muse, mutect2, varscan2
- ME3 | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV62772115; called by muse, mutect2, varscan2
- MET | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs761951444, COSV59260561, COSV59264666; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MFN2 | c.597C>T p.D199= | Splice Region (SNP) | VAF 15/79 reads (19%) | catalogued as rs1205882839, COSV52422160; called by muse, mutect2, varscan2
- MKRN3 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as rs772695029, COSV58809666, COSV58810959; called by mutect2, varscan2
- MMP19 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV59451200; called by muse, mutect2
- MMP20 | c.351G>A p.W117* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV52775262; called by muse, mutect2
- MRGPRX1 | c.268A>C p.I90L | Missense Mutation (SNP) | VAF 34/331 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV57106989; called by muse, mutect2, varscan2
- MROH8 | c.1057C>T p.L353F | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.207); catalogued as COSV54119543; called by muse, mutect2
- MTHFD1 | c.1396C>T p.H466Y | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV53699940; called by muse, varscan2
- MUC16 | c.38650G>A p.E12884K | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.931); catalogued as COSV67454159; called by muse, mutect2, varscan2
- MUC16 | c.17086G>A p.E5696K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.096); catalogued as COSV67462415; called by muse, mutect2, varscan2
- MUC17 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 89/270 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV60287055; called by muse, mutect2, varscan2
- MUC17 | c.4910C>T p.P1637L | Missense Mutation (SNP) | VAF 53/366 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV60287064; called by muse, mutect2, varscan2
- MUC17 | c.11755C>T p.P3919S | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.103); catalogued as rs865774883, COSV60281359; called by muse, mutect2, varscan2
- MUC5AC | c.14252T>G p.L4751R | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.131); catalogued as COSV100611390; called by muse, mutect2, varscan2
- MYO1F | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs773707121; called by muse, mutect2, varscan2
- MYO1H | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV60444034; called by muse, mutect2, varscan2
- NETO1 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV55001912, COSV55004052; called by muse, mutect2, varscan2
- NKX3-1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66511999; called by muse, mutect2, varscan2
- NKX6-1 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 11/63 reads (17%) | catalogued as COSV55684574, COSV55684616; called by muse, mutect2, varscan2
- NLRP10 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as COSV60778439, COSV60780870; called by muse, mutect2, varscan2
- NOS1AP | c.344G>A p.R115K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62634339; called by muse, mutect2, varscan2
- NPY5R | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.209); catalogued as COSV58451831; called by muse, mutect2, varscan2
- NR4A3 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs1159997688, COSV58243100; called by muse, varscan2
- NRXN3 | c.2833A>C p.S945R (on ENST00000335750 / NM_001330195.2; = p.S572R on NM_004796.6) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59742660; called by muse, mutect2, varscan2
- NSUN7 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.013); catalogued as COSV57273600; called by muse, mutect2, varscan2
- NUP98 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61431526; called by muse, mutect2, varscan2
- NWD1 | c.3857C>T p.S1286F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.823); catalogued as COSV60341512; called by muse, mutect2, varscan2
- OR10A7 | c.266G>A p.R89K | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV58278247; called by muse, mutect2, varscan2
- OR10J1 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.616); catalogued as rs760293762, COSV71128754; called by muse, mutect2, varscan2
- OR2B6 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV55128830, COSV99773718; called by muse, mutect2, varscan2
- OR4A16 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.082); catalogued as rs575051490, COSV59042137; called by muse, mutect2, varscan2
- OR4X2 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56582840; called by muse, mutect2, varscan2
- OR51L1 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV58624530; called by muse, mutect2, varscan2
- OR52R1 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV61888234; called by mutect2, varscan2
- OR5D18 | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.12); catalogued as rs1050935866, COSV61736954; called by mutect2, varscan2
- OR5M1 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV73202093; called by muse, mutect2, varscan2
- OR5P2 | c.254G>A p.R85K | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV61490453; called by muse, mutect2, varscan2
- OR6C3 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs868303067, COSV65571047; called by muse, mutect2, varscan2
- OR6C6 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV64455527; called by muse, mutect2, varscan2
- OR8D1 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.185); catalogued as COSV63441945; called by muse, mutect2
- OR8H2 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 45/278 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57943721; called by muse, mutect2, varscan2
- OR9G4 | c.815A>C p.K272T | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57248367; called by muse, mutect2, varscan2
- OSMR | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57084312; called by muse, mutect2, varscan2
- OXGR1 | c.884C>T p.T295I | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.097); catalogued as COSV53656751; called by muse, mutect2, varscan2
- P2RY14 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs775411484, COSV56377115; called by muse, mutect2, varscan2
- P4HA2 | c.1537+2T>G p.X513_splice | Splice Site (SNP) | VAF 12/60 reads (20%) | catalogued as COSV51324750; called by muse, varscan2
- PAPPA2 | c.3172G>A p.D1058N | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.27); catalogued as rs1353166778, COSV62793572; called by muse, mutect2, varscan2
- PASD1 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV64855043; called by muse, mutect2, varscan2
- PASK | c.3830C>T p.S1277F | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV52151883; called by muse, mutect2, varscan2
- PAX1 | c.662T>G p.L221R | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68271697; called by muse, mutect2, varscan2
- PCDHGB3 | c.1508C>T p.S503F | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54030922; called by muse, mutect2, varscan2
- PCLO | c.5579C>T p.S1860L | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61630354; called by muse, mutect2, varscan2
- PDE1A | c.380C>G p.A127G | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100115965, COSV59521861, COSV59539039; called by muse, mutect2, varscan2
- PGK2 | c.836G>A p.R279K | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs919364563, COSV59163599; called by muse, mutect2, varscan2
- PKHD1L1 | c.2909G>A p.G970E | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as rs1396860276, COSV65742046; called by muse, mutect2, varscan2
- PLPP3 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64839298; called by muse, mutect2, varscan2
- PLXDC2 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.895); catalogued as COSV65903306; called by muse, mutect2, varscan2
- PNKD | c.370A>G p.I124V | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.047); catalogued as rs909331529, COSV51231837; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLD1 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV70954980; called by muse, mutect2
- POLE | c.1819C>T p.L607F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV57679355; called by muse, mutect2, varscan2
- POM121L12 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV68692825; called by muse, mutect2
- PPP4R4 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.026); catalogued as COSV58558308; called by muse, mutect2, varscan2
- PRAMEF1 | c.665G>A p.R222K | Missense Mutation (SNP) | VAF 80/496 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as rs1178735902, COSV60008573, COSV60009033; called by muse, mutect2, varscan2
- PRAMEF2 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.217); catalogued as rs267597981, COSV53574945; called by muse, mutect2, varscan2
- PRB1 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 42/260 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV53703419; called by muse, mutect2, varscan2
- PRB2 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 62/394 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV66982922; called by muse, varscan2
- PRKAA2 | c.1611G>A p.M537I | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV64803490; called by muse, mutect2, varscan2
- PRKD1 | c.2035C>T p.P679S | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.326); catalogued as COSV59567054; called by muse, mutect2, varscan2
- PRRG1 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as rs782135730, COSV66157216; called by muse, mutect2, varscan2
- PSG2 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.216); catalogued as COSV61545145; called by muse, mutect2, varscan2
- PSG7 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); catalogued as COSV68444999; called by muse, mutect2, varscan2
- PSMB4 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV51850911; called by muse, mutect2, varscan2
- PTPRB | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs184275696, COSV54232350, COSV99715331; called by muse, mutect2, varscan2
- PTPRE | c.1000C>T p.H334Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54550191; called by muse, mutect2
- QPCTL | c.718T>G p.S240A | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as COSV50003784; called by muse, mutect2, varscan2
- RAB3IP | c.654+2T>C p.X218_splice (on ENST00000550536 / NM_175623.4; = p.X202_splice on NM_022456.5) | Splice Site (SNP) | VAF 7/56 reads (13%) | catalogued as COSV56083252; called by muse, mutect2, varscan2
- RANBP3L | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV56955378, COSV56958611; called by muse, mutect2, varscan2
- RBM25 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs1294642356, COSV56199734; called by muse, mutect2, varscan2
- RBMXL2 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1181651320, COSV60978666; called by mutect2, varscan2
- RDH8 | c.206A>C p.E69A (on ENST00000651512; = p.E49A on NM_015725.4) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as COSV50674774; called by muse, mutect2
- RELN | c.4874G>A p.G1625E | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58999278; called by muse, mutect2, varscan2
- REV3L | c.4189A>G p.I1397V | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs1562208442, COSV62618410; called by muse, mutect2, varscan2
- RGS8 | c.167C>T p.S56F (on ENST00000367556 / NM_001369564.2; = p.S74F on NM_033345.3) | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51116018; called by muse, mutect2, varscan2
- RSPH6A | c.1556C>T p.S519F | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV55571460; called by muse, mutect2
- RYR1 | c.2489G>A p.R830Q | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.087); catalogued as rs777191617, COSV62095839; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAGE1 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.925); catalogued as COSV61013059; called by muse, mutect2, varscan2
- SALL1 | c.2372G>A p.G791D | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV51756691; called by muse, mutect2, varscan2
- SAMD9 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760747768, COSV66072845; called by muse, mutect2, varscan2
- SCN4A | c.5275G>A p.D1759N | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs1015807829, COSV71126652; called by muse, mutect2, varscan2
- SCN7A | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (1); PolyPhen possibly damaging (0.459); catalogued as rs970770597, COSV69267984; called by muse, mutect2, varscan2
- SCN9A | c.4994A>G p.N1665S (on ENST00000303354; = p.N1654S on NM_002977.3) | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.726); catalogued as rs1401418949, COSV57601994; called by muse, mutect2, varscan2
- SERPINA10 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 13/66 reads (20%) | catalogued as COSV56228195; called by muse, mutect2, varscan2
- SHC3 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65438118; called by muse, mutect2, varscan2
- SI | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52274874; called by muse, mutect2, varscan2
- SLC1A6 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55669946; called by muse, mutect2, varscan2
- SLC38A4 | c.1120G>A p.G374R | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV56966598; called by muse, mutect2, varscan2
- SLC5A8 | c.1507C>T p.Q503* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as rs866560711, COSV73310357; called by muse, mutect2, varscan2
- SLC6A16 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.891); catalogued as COSV60027794; called by muse, mutect2, varscan2
- SLCO4C1 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60515186; called by muse, mutect2
- SNX19 | c.2648C>T p.S883F | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56285355; called by muse, mutect2, varscan2
- SORBS3 | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs1454202780, COSV53552688; called by muse, mutect2, varscan2
- SOX5 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV58622670; called by muse, mutect2, varscan2
- SPEF2 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56796291; called by muse, mutect2, varscan2
- SPEF2 | c.5420G>A p.G1807E | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs755690345, COSV57428902; called by muse, varscan2
- SPHKAP | c.767A>T p.E256V | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); catalogued as COSV60876775; called by muse, mutect2, varscan2
- SPNS3 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as rs1242781689, COSV100336804; called by muse, mutect2
- SPTLC2 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV53639574; called by muse, mutect2, varscan2
- SRPK3 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376822662, COSV54207296; called by muse, mutect2
- SRRD | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV53226075; called by muse, mutect2, varscan2
- STON2 | c.2635G>A p.E879K (on ENST00000649389 / NM_001366849.2; = p.E822K on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV50843939; called by muse, mutect2, varscan2
- SUSD5 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764739657; called by muse, mutect2, varscan2
- SYNE3 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV62079266; called by muse, mutect2, varscan2
- SYNPO2 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as rs1477045359, COSV61110043; called by muse, mutect2, varscan2
- SYT16 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV70855981; called by muse, mutect2, varscan2
- TBC1D9 | c.2195C>T p.T732I | Missense Mutation (SNP) | VAF 49/271 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV71307360; called by muse, mutect2, varscan2
- TENM2 | c.6758G>A p.R2253Q (on ENST00000518659 / NM_001122679.2; = p.R2014Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754754867, COSV69126892, COSV69132347; called by mutect2, varscan2
- TF | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.908); catalogued as COSV53919945; called by muse, mutect2, varscan2
- THSD4 | c.1645G>A p.G549S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as COSV55968778; called by muse, mutect2, varscan2
- TIAM2 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs151266968; called by muse, mutect2, varscan2
- TKTL2 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV54918560; called by muse, mutect2, varscan2
- TLR2 | c.1103G>A p.S368N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.778); catalogued as COSV52606046; called by muse, varscan2
- TLR2 | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs770658906; called by muse, varscan2
- TLR2 | c.1217G>A p.G406E | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs773976655; called by muse, varscan2
- TMEM168 | c.958C>T p.H320Y | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.584); catalogued as COSV57180490; called by muse, mutect2, varscan2
- TMEM45B | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV99859192; called by muse, mutect2, varscan2
- TMPRSS11B | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.812); catalogued as COSV60292145; called by mutect2, varscan2
- TNNT3 | c.169C>T p.P57S (on ENST00000397301 / NM_001367846.1; = p.P46S on NM_006757.4) | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs772115660, COSV53486369; called by muse, mutect2, varscan2
- TRANK1 | c.8270C>T p.S2757F | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as rs779170288, COSV57148553; called by muse, mutect2, varscan2
- TRANK1 | c.3104G>A p.G1035D | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1373300213, COSV57148589; called by muse, mutect2, varscan2
- TRIM22 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.325); catalogued as COSV66090740; called by muse, mutect2, varscan2
- TRO | c.3703A>C p.T1235P | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.09); catalogued as COSV51500822; called by muse, mutect2, varscan2
- TROAP | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV57743896, COSV99226810; called by muse, mutect2, varscan2
- TRPC4AP | c.1525G>T p.D509Y | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); catalogued as COSV52679221; called by muse, mutect2, varscan2
- TRPM6 | c.2782C>T p.R928* | Nonsense Mutation (SNP) | VAF 23/93 reads (25%) | catalogued as rs778418403, CM056712, COSV62508733; called by muse, mutect2, varscan2
- TSGA10 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.693); catalogued as rs1321980563, COSV61823570; called by muse, mutect2, varscan2
- TSPAN11 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1368429089, COSV53816255, COSV53818019; called by muse, mutect2, varscan2
- TTN | c.73394C>T p.T24465I (on ENST00000591111; = p.T17041I on NM_003319.4) | Missense Mutation (SNP) | VAF 33/179 reads (18%) | PolyPhen benign (0.359); catalogued as COSV60018013; called by muse, mutect2, varscan2
- TTN | c.64364C>G p.S21455C (on ENST00000591111; = p.S14031C on NM_003319.4) | Missense Mutation (SNP) | VAF 34/162 reads (21%) | PolyPhen benign (0.391); catalogued as COSV60018055; called by muse, mutect2, varscan2
- TTN | c.48043G>A p.G16015R (on ENST00000591111; = p.G8591R on NM_003319.4) | Missense Mutation (SNP) | VAF 20/99 reads (20%) | PolyPhen probably damaging (1); catalogued as rs1269389543, COSV60018108; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.27434G>A p.G9145E (on ENST00000591111; = p.G8218E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/158 reads (21%) | PolyPhen possibly damaging (0.56); catalogued as rs866946485, COSV59953892; called by muse, mutect2, varscan2
- TTN | c.5254C>T p.R1752C (on ENST00000591111; = p.R1706C on NM_003319.4) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | PolyPhen probably damaging (0.998); catalogued as rs1259833413, COSV100600808, COSV59989131; called by muse, mutect2, varscan2
- TWSG1 | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50814578, COSV50814904; called by muse, mutect2, varscan2
- UGT2B10 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV55320014; called by muse, mutect2, varscan2
- USH2A | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV56362150; called by muse, mutect2, varscan2
- USP29 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54142223; called by muse, varscan2
- USP6NL | c.1846C>T p.P616S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.001); catalogued as COSV53208942; called by muse, mutect2, varscan2
- UTP20 | c.1868C>T p.S623F | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV55376201; called by muse, mutect2, varscan2
- VN1R5 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 19/108 reads (18%) | catalogued as rs1446134180; called by muse, mutect2, varscan2
- VRTN | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.554); catalogued as COSV56439827; called by muse, mutect2, varscan2
- XIRP2 | c.1966G>A p.E656K (on ENST00000628543; = p.E831K on NM_152381.6) | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV54679776, COSV99748346; called by muse, mutect2, varscan2
- XIRP2 | c.6992G>A p.G2331E (on ENST00000628543; = p.G2506E on NM_152381.6) | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54715957; called by muse, mutect2, varscan2
- XKR4 | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs745961938, COSV59312652; called by muse, mutect2, varscan2
- XPC | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.154); catalogued as COSV53204168, COSV53204741; called by muse, mutect2, varscan2
- ZBTB7B | c.787C>T p.P263S (on ENST00000292176; = p.P297S on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.052); catalogued as COSV52692333; called by muse, mutect2
- ZC3HAV1 | c.2353C>A p.L785I | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54295360; called by muse, mutect2, varscan2
- ZDBF2 | c.6244C>T p.H2082Y | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); catalogued as COSV65625143; called by muse, mutect2, varscan2
- ZDHHC8 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV57709995; called by muse, mutect2, varscan2
- ZNF232 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.402); catalogued as COSV51503211; called by muse, mutect2, varscan2
- ZNF283 | c.1273C>T p.H425Y | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1357418792, COSV61031150; called by muse, mutect2, varscan2
- ZNF334 | c.775C>T p.H259Y | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.378); catalogued as COSV61618439; called by muse, mutect2, varscan2
- ZNF536 | c.1816G>A p.D606N | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as rs866522049, COSV62823242; called by muse, mutect2, varscan2
- ZPLD1 | c.869C>T p.S290F (on ENST00000466937 / NM_001329788.1; = p.S306F on NM_175056.2) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60351658; called by muse, mutect2, varscan2
- ADCY7 | c.3227G>A p.G1076E | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- DNAH8 | c.12474_12476del p.K4158_T4159delinsN | In Frame Del (DEL) | VAF 21/150 reads (14%) | called by mutect2, pindel, varscan2
- DST | c.4922C>T p.T1641I | Missense Mutation (SNP) | VAF 58/381 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- EZR | c.1391A>T p.H464L | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- FYB2 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); called by muse, mutect2
- GALNT14 | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR141 | c.896G>A p.W299* | Nonsense Mutation (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2, varscan2
- KLK15 | c.458C>T p.T153I | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.351); called by muse, mutect2
- LIME1 | c.710C>T p.T237I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRP1 | c.4075T>A p.Y1359N | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LRRK1 | c.5694G>A p.M1898I | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRK1 | c.5695G>A p.D1899N | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROBO2 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SNX19 | c.2440C>T p.P814S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0.003); called by muse, mutect2
- SPANXB1 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 38/323 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); called by muse, varscan2
- TRAV12-3 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- TRAV5 | c.273A>T p.K91N | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- UGT3A1 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2
- UGT3A1 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- AARS2 | c.1224C>T p.F408= | Silent (SNP) | VAF 22/119 reads (18%) | catalogued as COSV55114513; called by muse, mutect2, varscan2
- ABCC8 | c.3471C>T p.S1157= | Silent (SNP) | VAF 40/219 reads (18%) | catalogued as COSV56849683; called by muse, mutect2, varscan2
- ADAM28 | c.1521G>A p.G507= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV56100085; called by muse, mutect2, varscan2
- ADGRG4 | c.1353G>A p.V451= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV54954905; called by muse, mutect2, varscan2
- ADGRV1 | c.12210C>T p.V4070= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV101315538, COSV67984133; called by muse, mutect2
- ARPP21 | c.531C>T p.F177= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV51793939; called by mutect2, varscan2
- ATP13A4 | c.2448C>T p.I816= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as COSV61319627; called by muse, mutect2, varscan2
- C10orf62 | c.507G>A p.R169= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as rs1288764242, COSV65705192; called by muse, mutect2, varscan2
- C1QL4 | c.564C>T p.D188= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs766370434, COSV57743900; called by mutect2, varscan2
- C3 | c.3324C>T p.I1108= | Silent (SNP) | VAF 35/130 reads (27%) | catalogued as rs776045828, COSV55572255; called by muse, mutect2, varscan2
- CD2BP2 | c.267C>T p.P89= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as rs1407765282, COSV59768656; called by muse, mutect2, varscan2
- CD33 | c.951T>C p.H317= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV51801366; called by muse, mutect2, varscan2
- CGNL1 | c.2016G>A p.L672= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs946082061, COSV55567055; called by muse, mutect2
- CHD5 | c.1764G>A p.K588= | Silent (SNP) | VAF 25/129 reads (19%) | catalogued as COSV52413279; called by muse, mutect2, varscan2
- CYP21A2 | c.168C>T p.F56= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs756320878, COSV64478209; called by mutect2, varscan2
- CYP4A11 | c.1197C>T p.F399= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV60223250; called by muse, varscan2
- CYP4A11 | c.99G>A p.K33= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as rs1339255208, COSV60223265; called by muse, mutect2, varscan2
- DIPK2B | c.735C>T p.L245= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs758307048, COSV67641094; called by muse, mutect2, varscan2
- DNAH5 | c.11652C>T p.A3884= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV54220914; called by muse, mutect2, varscan2
- DNAL4 | c.57C>T p.F19= | Silent (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2, varscan2
- DNMT1 | c.1593C>A p.I531= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV61580803; called by muse, mutect2, varscan2
- DPYD | c.2667C>T p.I889= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV64594757, COSV64603078; called by muse, mutect2, varscan2
- DRC3 | c.516G>A p.E172= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV58262655; called by muse, mutect2, varscan2
- DSEL | c.2856C>T p.P952= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV59491062; called by muse, mutect2, varscan2
- EZR | c.1392C>T p.H464= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs1003792934; called by muse, mutect2, varscan2
- FPR1 | c.648C>T p.I216= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as rs775825440, COSV59051904; called by muse, mutect2, varscan2
- FUT1 | c.498C>T p.G166= | Silent (SNP) | VAF 44/208 reads (21%) | catalogued as COSV59568141; called by muse, mutect2, varscan2
- GABRB2 | c.810T>G p.A270= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs984057129, COSV50909369; called by muse, mutect2, varscan2
- GPR50 | c.462C>T p.I154= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV54438753; called by muse, mutect2, varscan2
- HDAC1 | c.756C>T p.F252= | Silent (SNP) | VAF 40/204 reads (20%) | catalogued as rs1343144178, COSV61481998; called by muse, mutect2, varscan2
- HS3ST2 | c.942G>A p.L314= | Silent (SNP) | VAF 32/206 reads (16%) | catalogued as COSV54461343; called by muse, mutect2, varscan2
- IGHV3-66 | c.93C>T p.I31= | Silent (SNP) | VAF 18/242 reads (7%) | called by muse, mutect2
- IGKV1-17 | c.51C>T p.F17= | Silent (SNP) | VAF 26/194 reads (13%) | called by muse, varscan2
- INTS1 | c.2538C>T p.P846= | Silent (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- IRF3 | c.102C>T p.F34= | Silent (SNP) | VAF 22/123 reads (18%) | catalogued as rs746052263, COSV55863033; called by muse, mutect2, varscan2
- ITIH2 | c.702C>T p.F234= | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as rs148694864; called by muse, mutect2, varscan2
- KCNB2 | c.933C>T p.I311= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs997351531, COSV73049947; called by muse, mutect2
- KIAA1217 | c.4731C>T p.F1577= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as COSV56815903; called by muse, mutect2, varscan2
- KLHL21 | c.1167C>T p.A389= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs372952934, COSV66553036; called by muse, varscan2
- KLK13 | c.711C>T p.F237= | Silent (SNP) | VAF 32/134 reads (24%) | catalogued as COSV50067036; called by muse, mutect2, varscan2
- KRT33A | c.552G>A p.K184= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV50365760; called by muse, mutect2, varscan2
- LATS2 | c.2113C>T p.L705= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV66875052; called by muse, mutect2, varscan2
- LGR5 | c.2361C>T p.F787= | Silent (SNP) | VAF 112/721 reads (16%) | catalogued as COSV57004609; called by muse, mutect2, varscan2
- LILRA1 | c.462C>T p.F154= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV52180187; called by muse, varscan2
- LIME1 | c.711C>T p.T237= | Silent (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2
- LRP5 | c.1401C>T p.H467= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs113518978; called by muse, varscan2
- MARCO | c.243C>T p.F81= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as rs75633112, COSV59053927; called by muse, mutect2, varscan2
- MECOM | c.219G>A p.T73= (on ENST00000468789 / NM_001105078.4; = p.T261= on NM_004991.4) | Silent (SNP) | VAF 27/198 reads (14%) | catalogued as rs150481592; called by muse, mutect2, varscan2
- MGAT4C | c.544C>T p.L182= | Silent (SNP) | VAF 27/202 reads (13%) | catalogued as COSV59832200; called by muse, mutect2, varscan2
- MRGPRX1 | c.711C>T p.F237= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV57106307; called by muse, varscan2
- MYH1 | c.5115C>T p.I1705= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as rs145122906, COSV56844388; called by muse, mutect2, varscan2
- MYO1F | c.729G>A p.Q243= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs745602882; called by muse, mutect2, varscan2
- NME9 | c.162C>T p.I54= (on ENST00000333911 / NM_001349024.2; = p.I32= on NM_178130.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/334 reads (15%) | catalogued as rs377579898, COSV58618259; called by muse, mutect2, varscan2
- NOTCH2 | c.2298C>T p.C766= | Silent (SNP) | VAF 139/792 reads (18%) | catalogued as COSV56690152; called by muse, mutect2, varscan2
- NPHP1 | c.1941C>T p.F647= (on ENST00000393272 / NM_207181.4; = p.F648= on NM_000272.5) | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as COSV57208236; called by muse, mutect2, varscan2
- NREP | c.186C>T p.I62= | Silent (SNP) | VAF 28/133 reads (21%) | catalogued as COSV57405101; called by muse, mutect2, varscan2
- OLFML2B | c.2031C>T p.F677= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as rs1346925350, COSV54194943; called by muse, mutect2, varscan2
- OR10G8 | c.117G>A p.G39= | Silent (SNP) | VAF 41/155 reads (26%) | catalogued as COSV70908478; called by muse, mutect2, varscan2
- OR10H4 | c.60C>T p.F20= | Silent (SNP) | VAF 49/187 reads (26%) | catalogued as COSV59061722; called by muse, mutect2, varscan2
- OR11G2 | c.456C>T p.F152= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs747476876, COSV62131985, COSV62132051, COSV62132912; called by muse, mutect2, varscan2
- OR2AE1 | c.235C>T p.L79= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs1414995761; called by muse, mutect2, varscan2
- OR2AE1 | c.234C>T p.I78= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as COSV60389833; called by muse, mutect2, varscan2
- OR2T35 | c.849C>T p.P283= | Silent (SNP) | VAF 4/11 reads (36%) | called by mutect2, varscan2
- OR4K17 | c.648C>T p.I216= | Silent (SNP) | VAF 10/123 reads (8%) | catalogued as rs1253803864, COSV59647945; called by muse, mutect2
- OR52R1 | c.393C>T p.F131= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV61888242, COSV61888951; called by muse, varscan2
- OR5AK2 | c.915G>A p.G305= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV58804165; called by muse, mutect2
- OR6C65 | c.186G>A p.R62= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV65568453; called by muse, mutect2, varscan2
- OR6C74 | c.475C>T p.L159= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as rs1223723596; called by muse, mutect2, varscan2
- OR8S1 | c.808T>C p.L270= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as COSV59599794; called by muse, mutect2, varscan2
- PCDH17 | c.1914C>T p.I638= | Silent (SNP) | VAF 18/122 reads (15%) | catalogued as rs780891643, COSV64973629, COSV64975900; called by muse, mutect2, varscan2
- PCDHA10 | c.570C>T p.F190= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as COSV56496716; called by muse, mutect2, varscan2
- PCDHA12 | c.2292G>A p.P764= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV56496740, COSV56501060; called by mutect2, varscan2
- PDGFD | c.912A>T p.G304= | Silent (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2
- PI3 | c.342C>T p.F114= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as rs371430509; called by mutect2, varscan2
- PLA2G4A | c.375C>T p.N125= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs1027845535, COSV66553602; called by muse, mutect2
- POLR3B | c.2955G>A p.G985= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV57278446; called by muse, mutect2, varscan2
- PRODH2 | c.615G>A p.E205= (on ENST00000301175; = p.E129= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV56559523; called by muse, mutect2
- PSIP1 | c.1335T>A p.A445= | Silent (SNP) | VAF 29/134 reads (22%) | catalogued as COSV66254392; called by muse, mutect2, varscan2
- RGS9 | c.633G>A p.P211= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs764942505, COSV52222899; called by muse, mutect2, varscan2
- RIC3 | c.448C>T p.L150= | Silent (SNP) | VAF 24/103 reads (23%) | called by muse, mutect2, varscan2
- RRP9 | c.459C>T p.V153= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs745635865, COSV51754110; called by muse, mutect2, varscan2
- RYR1 | c.5241C>T p.F1747= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV62095845; called by muse, mutect2, varscan2
- SETBP1 | c.4164G>A p.S1388= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs773446890, COSV56320238; called by muse, mutect2, varscan2
- SGCZ | c.720C>T p.L240= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV101169656, COSV66013182; called by muse, mutect2, varscan2
- SLC22A9 | c.12G>A p.Q4= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV54166994; called by muse, mutect2, varscan2
- SLC45A1 | c.1377C>T p.I459= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as COSV57094956; called by muse, mutect2, varscan2
- SLC4A11 | c.1674C>T p.A558= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV66261683; called by muse, mutect2, varscan2
- SLC4A8 | c.870C>T p.F290= | Silent (SNP) | VAF 41/202 reads (20%) | catalogued as COSV60651319; called by muse, mutect2, varscan2
- SMARCAD1 | c.249C>T p.F83= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV62773701; called by muse, mutect2, varscan2
- SPEF2 | c.5403G>A p.R1801= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs765675618, COSV57428881; called by muse, varscan2
- STEAP3 | c.1209C>T p.L403= | Silent (SNP) | VAF 26/145 reads (18%) | catalogued as rs752735656, COSV61528814; called by muse, mutect2, varscan2
- SYNE2 | c.672A>G p.R224= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs753781068, COSV58360606; called by mutect2, varscan2
- SYT17 | c.825C>T p.L275= | Silent (SNP) | VAF 27/139 reads (19%) | catalogued as COSV62546020; called by muse, mutect2, varscan2
- TCN1 | c.510C>T p.F170= | Silent (SNP) | VAF 19/112 reads (17%) | catalogued as COSV57253063; called by muse, mutect2, varscan2
- TFF1 | c.6C>T p.A2= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV52298440; called by muse, mutect2
- TLR3 | c.1890C>T p.F630= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as rs145921610; called by muse, mutect2, varscan2
- TNFRSF4 | c.525G>A p.Q175= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV55418995; called by muse, mutect2, varscan2
- TNFSF9 | c.732C>T p.I244= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV55538198; called by muse, mutect2
- TRAPPC6A | c.234C>T p.F78= (on ENST00000585934 / NM_001270891.2; = p.F92= on NM_024108.3) | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as COSV50065150; called by muse, mutect2, varscan2
- TRAPPC8 | c.534T>C p.D178= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV51970248; called by muse, mutect2
- TRHDE | c.3045C>T p.F1015= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV53842088, COSV53857232; called by muse, mutect2, varscan2
- TSGA10 | c.858C>T p.S286= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV61822555; called by muse, mutect2, varscan2
- TTN | c.46387C>T p.L15463= (on ENST00000591111; = p.L8039= on NM_003319.4) | Silent (SNP) | VAF 56/291 reads (19%) | catalogued as rs1060503959, COSV60018161; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.13218C>T p.I4406= (on ENST00000591111; = p.I4360= on NM_003319.4) | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs397517479, COSV60018209; ClinVar: likely benign; called by mutect2, varscan2
- UGT1A10 | c.414G>A p.K138= | Silent (SNP) | VAF 23/144 reads (16%) | catalogued as rs1322316630, COSV60837500; called by muse, mutect2, varscan2
- VRTN | c.426C>T p.S142= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV56440744; called by muse, mutect2, varscan2
- WFDC10A | c.105C>T p.S35= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV58096584; called by muse, mutect2
- YTHDF1 | c.1156C>T p.L386= | Silent (SNP) | VAF 24/133 reads (18%) | catalogued as COSV64832845; called by muse, mutect2, varscan2
- ZEB1 | c.2406C>T p.I802= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs749059172, COSV58037756; called by muse, mutect2, varscan2
- ZNF615 | c.2115G>A p.E705= | Silent (SNP) | VAF 42/159 reads (26%) | catalogued as COSV65032970; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83196G>A | Intron (SNP) | VAF 57/228 reads (25%) | called by muse, mutect2, varscan2
- ANKS1B | c.2420-18C>T | Intron (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100227009; called by muse, mutect2, varscan2
- BRMS1L | c.*2C>T | 3'UTR (SNP) | VAF 21/120 reads (18%) | catalogued as COSV99396609; called by muse, mutect2, varscan2
- CIT | c.4729-457C>T | Intron (SNP) | VAF 23/126 reads (18%) | called by muse, mutect2, varscan2
- DEFB119 | c.61+1325G>A | Intron (SNP) | VAF 10/86 reads (12%) | catalogued as rs1408273034, COSV59265785; called by muse, mutect2, varscan2
- MIR382 | n.54C>T | RNA (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- MYH2 | c.-1C>T | 5'UTR (SNP) | VAF 7/26 reads (27%) | catalogued as rs762335606, COSV99819743; called by muse, mutect2
- NXF5 | n.654G>A | RNA (SNP) | VAF 26/110 reads (24%) | catalogued as COSV53790688, COSV53792699; called by muse, varscan2
- SNORD114-30 | n.57G>A | RNA (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- SSX3 | c.466+431C>T | Intron (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2, varscan2
- TRIML2 | c.*2C>T | 3'UTR (SNP) | VAF 22/78 reads (28%) | catalogued as COSV100455984; called by muse, mutect2, varscan2
